TARGET case TARGET-40-NAAWDM — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/fb19af35-1b1e-52c1-a683-83a434fcc074

Biospecimens (1 sample)
- Sample TARGET-40-NAAWDM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
